TCGA case TCGA-QQ-A8VF — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4d016bd8-006c-4a90-ace7-28f151624112

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 70.3 years (25,682 days); Year of diagnosis: 2005; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes.
   Pathology details: Measurement type: Pathologic; Tumor burden: 12.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 9; Tumor length measurement: 12; Tumor width measurement: 9.

Follow-up (3 entries)
- Days to follow up: 2,841 days (7.8 years); Disease response: Tumor Free.
- Days to follow up: 2,989 days (8.2 years); Disease response: Tumor Free.
- Days to follow up: 3,406 days (9.3 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A8VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-QQ-A8VF-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QQ-A8VF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A8VF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 9; Lesion pathologic depth: 9.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,406 days; disease-specific survival: no event (censored), 3,406 days; progression-free interval: no event (censored), 3,406 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A8VF-01A-11D-A37B-01): tumor purity 0.79, ploidy 2.5, whole-genome doublings 1.
